FM case AD9070 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/b45ba8a6-4741-4195-ac1d-1a800db700d1

Male, 70.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
